FM case AD14021 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/a4fb3209-839f-45d1-9b6b-e68786e3c8e7

Male, 51.7 years: Adenosquamous carcinoma (ICD-O-3 8560/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
